CCDI case PBCJRP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4688c837-8af0-4c0a-bd07-24807dc3cb35

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.4 years (3,797 days).

Biospecimens (3 samples)
- Sample 0DU3KC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU3LN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU3MG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
